Somatic mutation profile of tumor specimen TCGA-CN-A49A-01A (aliquot TCGA-CN-A49A-01A-11D-A24D-08) from TCGA case TCGA-CN-A49A, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Palate, NOS; AJCC pathologic stage: Stage IVB; Tumor grade: G2; Age at diagnosis: 60.2 years (21,995 days).
Specimen TCGA-CN-A49A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a4320d92-d144-48b4-a5eb-c1afe45d9429.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A49A-10A (Blood Derived Normal), aliquot TCGA-CN-A49A-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38853e28-2f14-4069-a31d-9dd6536b3ea4

The open-access MAF lists 123 somatic variants for this specimen: 90 protein-altering or splice-affecting, 31 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 79, Silent 31, Nonsense Mutation 8, Frame Shift Del 2, Splice Site 1, 5'Flank 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHDC1 | c.2380C>T p.Q794* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as rs1553158947, COSV99899797; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB8 | c.1309C>T p.R437W (on ENST00000297504 / NM_001282291.2; = p.R420W on NM_007188.5) | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs771806920, COSV52509514; called by muse, mutect2, varscan2
- ALMS1 | c.10243T>C p.S3415P | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.029); catalogued as COSV100044220; called by muse, mutect2, varscan2
- ANKRD30A | c.2546C>T p.P849L (on ENST00000611781; = p.P793L on NM_052997.2) | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV64619834; called by muse, mutect2, varscan2
- ARHGEF17 | c.6072G>T p.M2024I | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0.011); catalogued as COSV99737262; called by muse, mutect2, varscan2
- ATP13A5 | c.1437A>C p.Q479H | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100665906; called by muse, mutect2, varscan2
- AXDND1 | c.2255C>A p.T752K | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV100858780; called by muse, mutect2, varscan2
- BRIP1 | c.1853C>G p.S618* | Nonsense Mutation (SNP) | VAF 15/57 reads (26%) | catalogued as COSV99371347; called by muse, mutect2, varscan2
- BRWD3 | c.4832C>T p.S1611F | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.462); catalogued as COSV100956679; called by muse, mutect2, varscan2
- C4A | c.3572A>T p.H1191L | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs766070113, COSV101418371; called by muse, mutect2
- C9 | c.1228G>C p.E410Q | Missense Mutation (SNP) | VAF 31/76 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.163); catalogued as COSV54682151, COSV99662728; called by muse, mutect2, varscan2
- CDK14 | c.893G>A p.R298K (on ENST00000380050 / NM_001287135.2; = p.R280K on NM_012395.3) | Missense Mutation (SNP) | VAF 22/162 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as COSV99727662; called by muse, mutect2, varscan2
- CEP131 | c.2755G>A p.E919K (on ENST00000269392 / NM_001319228.2; = p.E916K on NM_014984.4) | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99489240; called by muse, mutect2, varscan2
- CEP170 | c.1485C>A p.D495E | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV100318150; called by muse, mutect2, varscan2
- CFAP299 | c.152G>A p.R51Q | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.606); catalogued as rs375423593, COSV100812571, COSV63881323; called by muse, mutect2, varscan2
- CFHR2 | c.550C>T p.L184F | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.837); catalogued as COSV100804415; called by muse, mutect2, varscan2
- CHSY3 | c.1735G>C p.D579H | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as rs1004643309, COSV100520239; called by muse, mutect2, varscan2
- CLSTN2 | c.2204C>A p.S735Y | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV101515729, COSV71724212; called by muse, mutect2, varscan2
- COL19A1 | c.2201G>A p.R734Q | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs201036860, COSV59569463; called by muse, mutect2, varscan2
- CPSF1 | c.3817G>A p.D1273N | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100450815; called by muse, mutect2
- CYLC2 | c.948G>C p.K316N | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.745); catalogued as rs532036391, COSV100872645, COSV66336392, COSV66339344; called by mutect2, varscan2
- DIS3L | c.470G>A p.R157K (on ENST00000319212 / NM_001143688.3; = p.R74K on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100055735, COSV59912726; called by muse, mutect2, varscan2
- ELAVL2 | c.475G>C p.D159H | Missense Mutation (SNP) | VAF 13/88 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV56361201, COSV56368615, COSV99807544; called by muse, mutect2, varscan2
- FAM171B | c.268A>T p.N90Y | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as COSV100489167; called by muse, mutect2, varscan2
- FFAR3 | c.754G>A p.G252S | Missense Mutation (SNP) | VAF 27/211 reads (13%) | SIFT tolerated (0.36); PolyPhen benign (0.075); catalogued as rs540255880, COSV100588334; called by muse, mutect2, varscan2
- FKBP8 | c.682G>A p.G228S (on ENST00000222308 / NM_001308373.2; = p.G229S on NM_012181.5) | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762107899, COSV99724356; called by muse, mutect2, varscan2
- FLG | c.8525G>A p.R2842H | Missense Mutation (SNP) | VAF 83/1050 reads (8%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs556196419, COSV100910475, COSV64252567; called by muse, mutect2
- FLT4 | c.2675C>T p.A892V | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56121298, COSV99987729; called by muse, mutect2, varscan2
- FRY | c.8609A>T p.D2870V | Missense Mutation (SNP) | VAF 18/43 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100970073; called by muse, mutect2, varscan2
- FSTL5 | c.2365G>A p.E789K | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.79); PolyPhen benign (0.098); catalogued as rs760530893, COSV100062641; called by muse, mutect2
- FUT10 | c.1431C>G p.F477L | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.158); catalogued as COSV100567639; called by muse, mutect2, varscan2
- GON4L | c.5804C>A p.T1935N | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV99676257; called by muse, mutect2, varscan2
- GRSF1 | c.1123G>A p.E375K | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV99636155; called by muse, mutect2, varscan2
- HHIP | c.980C>T p.S327F | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99668138; called by muse, mutect2, varscan2
- HSD3B2 | c.653C>G p.S218C | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101027589; called by muse, mutect2, varscan2
- ITSN1 | c.563C>A p.S188Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.974); catalogued as COSV101180650, COSV66082550; called by muse, mutect2, varscan2
- KIF15 | c.2458G>T p.E820* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV100393427; called by muse, mutect2, varscan2
- KRTAP5-11 | c.283T>G p.S95A | Missense Mutation (SNP) | VAF 36/144 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.006); catalogued as COSV100651975; called by muse, mutect2, varscan2
- LAMA3 | c.821C>G p.S274C | Missense Mutation (SNP) | VAF 40/87 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100557920; called by muse, mutect2, varscan2
- LILRA2 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.645); catalogued as COSV99254168; called by muse, mutect2, varscan2
- LRRC4C | c.1057G>T p.A353S | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.372); catalogued as COSV53435750, COSV99074402, COSV99540347; called by muse, mutect2, varscan2
- MAB21L3 | c.870G>A p.W290* | Nonsense Mutation (SNP) | VAF 7/21 reads (33%) | catalogued as COSV101046563; called by muse, mutect2, varscan2
- MAP3K13 | c.1564C>G p.P522A | Missense Mutation (SNP) | VAF 48/101 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.54); catalogued as COSV99408282; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3148C>T p.R1050C | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99169987; called by muse, mutect2, varscan2
- MAPRE2 | c.235G>T p.E79* | Nonsense Mutation (SNP) | VAF 7/51 reads (14%) | catalogued as COSV100290952; called by muse, mutect2
- MED1 | c.311C>G p.T104R | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100328262; called by muse, mutect2, varscan2
- MINDY4 | c.1435G>T p.D479Y | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.764); catalogued as COSV99519489; called by muse, varscan2
- MMP14 | c.1285T>G p.F429V | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100314372; called by muse, mutect2, varscan2
- MUC16 | c.3278C>G p.S1093* | Nonsense Mutation (SNP) | VAF 13/65 reads (20%) | catalogued as COSV101197471; called by muse, mutect2, varscan2
- MX1 | c.742A>C p.K248Q | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99912931; called by muse, mutect2, varscan2
- MYBPC2 | c.3298C>G p.Q1100E | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.957); catalogued as rs111796788, COSV100732071; called by muse, varscan2
- NAMPT | c.1366G>A p.D456N | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT tolerated (0.39); PolyPhen benign (0.096); catalogued as COSV99748411; called by muse, mutect2, varscan2
- NAV3 | c.2972G>C p.R991T | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99897127; called by muse, mutect2, varscan2
- NDUFAF3 | c.230G>T p.G77V | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100455247; called by muse, mutect2, varscan2
- NRROS | c.2049G>C p.K683N | Missense Mutation (SNP) | VAF 49/178 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV100145680; called by muse, mutect2, varscan2
- OR5T1 | c.784A>G p.I262V | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.042); catalogued as COSV100479290; called by muse, mutect2, varscan2
- OR6A2 | c.201G>T p.M67I | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.122); catalogued as rs1169462014, COSV100215854; called by muse, mutect2, varscan2
- PBDC1 | c.511G>A p.V171I | Missense Mutation (SNP) | VAF 32/53 reads (60%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100972891; called by muse, mutect2, varscan2
- PCDHA8 | c.1398G>C p.E466D | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65337741; called by muse, mutect2, varscan2
- PHF24 | c.913C>T p.R305W | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs771816039, COSV99646369; called by muse, mutect2, varscan2
- PIK3CD | c.1036G>A p.G346R | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350006292, COSV100740648; called by muse, mutect2, varscan2
- PLEKHH1 | c.1076C>G p.S359C | Missense Mutation (SNP) | VAF 14/31 reads (45%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.469); catalogued as COSV100233575; called by muse, mutect2, varscan2
- POSTN | c.209G>T p.G70V | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101123548; called by muse, mutect2, varscan2
- PRDM9 | c.551G>A p.R184Q | Missense Mutation (SNP) | VAF 26/477 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.988); catalogued as rs779766814, COSV57012958, COSV99689947, COSV99691313; called by muse, mutect2
- PRND | c.262G>A p.G88S | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.956); catalogued as COSV99999776; called by muse, mutect2, varscan2
- PTH2R | c.921G>T p.W307C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99783069; called by muse, mutect2, varscan2
- RBBP4 | c.1231G>A p.D411N | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.65); catalogued as COSV100995438, COSV65130204; called by muse, mutect2, varscan2
- SERPINA3 | c.849G>C p.K283N | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV101261879; called by muse, mutect2
- SETBP1 | c.612C>A p.D204E | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.36); PolyPhen benign (0.218); catalogued as COSV99955552; called by muse, mutect2, varscan2
- SHOC1 | c.3076C>G p.P1026A | Missense Mutation (SNP) | VAF 117/254 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1345169119, COSV100598165; called by muse, mutect2, varscan2
- SLC2A14 | c.507C>G p.I169M | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.626); catalogued as COSV100534147; called by muse, mutect2, varscan2
- SMARCA2 | c.2551G>A p.D851N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as CM122573, COSV100571638; called by muse, mutect2, varscan2
- SRR | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 34/71 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs766468296, COSV60737804; called by muse, mutect2, varscan2
- TBCE | c.1171C>T p.H391Y (on ENST00000366601; = p.H454Y on NM_003193.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.191); catalogued as rs1451611643, COSV100783324; called by muse, mutect2, varscan2
- TMEM130 | c.1022T>A p.V341D | Missense Mutation (SNP) | VAF 95/158 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as COSV100229101; called by muse, mutect2, varscan2
- TRMT1L | c.1595C>G p.S532* | Nonsense Mutation (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100834776; called by muse, mutect2
- TTC21B | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 23/73 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as COSV99693109; called by muse, mutect2, varscan2
- UNC79 | c.7249T>C p.W2417R (on ENST00000393151 / NM_001346218.2; = p.W2240R on NM_020818.5) | Missense Mutation (SNP) | VAF 20/199 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99830321; called by muse, mutect2
- VCPIP1 | c.1041G>A p.W347* | Nonsense Mutation (SNP) | VAF 62/138 reads (45%) | catalogued as COSV100125668; called by muse, mutect2, varscan2
- VNN2 | c.907G>A p.E303K | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV100426995; called by muse, mutect2, varscan2
- WEE2 | c.539+1G>T p.X180_splice | Splice Site (SNP) | VAF 6/46 reads (13%) | catalogued as COSV101285297; called by muse, mutect2, varscan2
- ZCCHC14 | c.502G>A p.V168M (on ENST00000268616; = p.V305M on NM_015144.3) | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.041); catalogued as COSV99234774; called by muse, mutect2, varscan2
- ZFYVE26 | c.4252G>C p.E1418Q | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV100720757; called by muse, mutect2, varscan2
- ZMYM4 | c.3166G>C p.E1056Q | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as COSV100111342, COSV58908560; called by muse, mutect2, varscan2
- ZNF132 | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as COSV99571464; called by muse, mutect2, varscan2
- ZNF518A | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as COSV100283799; called by muse, mutect2, varscan2
- ZNF599 | c.971C>G p.S324C | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100251380; called by muse, mutect2, varscan2
- FAT1 | c.311del p.N104Ifs*9 | Frame Shift Del (DEL) | VAF 26/78 reads (33%) | called by pindel, varscan2
- SS18 | c.726_727del p.N242Kfs*12 | Frame Shift Del (DEL) | VAF 52/166 reads (31%) | called by mutect2, pindel, varscan2
- TRDV2 | c.212A>G p.E71G | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); called by muse, mutect2
- ACOT11 | c.1407C>T p.D469= | Silent (SNP) | VAF 5/24 reads (21%) | catalogued as rs1350941603, COSV100156806; called by muse, mutect2, varscan2
- ASB2 | c.1302C>T p.I434= | Silent (SNP) | VAF 14/127 reads (11%) | catalogued as COSV100279694; called by muse, varscan2
- BCS1L | c.927C>T p.F309= | Silent (SNP) | VAF 30/104 reads (29%) | catalogued as COSV99829274; called by muse, mutect2, varscan2
- CCDC87 | c.1335C>T p.A445= | Silent (SNP) | VAF 28/134 reads (21%) | catalogued as rs750886174, COSV100040294; called by muse, mutect2, varscan2
- CCL28 | c.96G>A p.T32= | Silent (SNP) | VAF 19/48 reads (40%) | catalogued as rs750897561, COSV100742088, COSV63149606; called by muse, mutect2, varscan2
- DAOA | c.201C>T p.D67= | Silent (SNP) | VAF 22/51 reads (43%) | catalogued as rs201139062, COSV100298761; called by muse, mutect2, varscan2
- DTX4 | c.1044C>T p.L348= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV57092828; called by muse, mutect2
- GBP7 | c.786G>A p.Q262= | Silent (SNP) | VAF 22/65 reads (34%) | catalogued as COSV99643630; called by muse, mutect2, varscan2
- GOLGA6A | c.2046G>A p.Q682= | Silent (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
- HPDL | c.711G>A p.A237= | Silent (SNP) | VAF 38/114 reads (33%) | catalogued as rs772040903, COSV100588258; called by muse, mutect2, varscan2
- HPS5 | c.1056C>T p.L352= (on ENST00000349215 / NM_181507.2; = p.L238= on NM_007216.4) | Silent (SNP) | VAF 23/117 reads (20%) | catalogued as COSV100752400; called by muse, mutect2, varscan2
- JAG1 | c.960T>C p.Y320= | Silent (SNP) | VAF 12/53 reads (23%) | catalogued as CM124879, COSV99653650; called by muse, mutect2, varscan2
- LILRA6 | c.906C>T p.L302= | Silent (SNP) | VAF 9/99 reads (9%) | catalogued as COSV54432973; called by muse, mutect2
- NDUFAF3 | c.231C>A p.G77= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV100455249; called by muse, mutect2, varscan2
- NLRP14 | c.2613A>G p.Q871= | Silent (SNP) | VAF 18/91 reads (20%) | catalogued as rs1182183112, COSV55064054; called by muse, mutect2, varscan2
- NRK | c.1917G>A p.L639= | Silent (SNP) | VAF 6/14 reads (43%) | catalogued as COSV99688750, COSV99689500; called by muse, mutect2, varscan2
- NRXN1 | c.4308C>T p.D1436= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as rs201630518, COSV100640885; called by muse, mutect2, varscan2
- PAK6 | c.1608C>G p.L536= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as COSV99545213; called by muse, mutect2, varscan2
- PAPPA2 | c.1293C>T p.T431= | Silent (SNP) | VAF 34/93 reads (37%) | catalogued as rs776538831, COSV100867285; called by muse, mutect2, varscan2
- PHRF1 | c.651C>G p.L217= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV99213943; called by muse, mutect2
- PLEC | c.11130C>T p.D3710= (on ENST00000322810 / NM_201380.4; = p.D3600= on NM_000445.5) | Silent (SNP) | VAF 85/230 reads (37%) | catalogued as rs782356658, COSV100520186; called by muse, mutect2, varscan2
- RALGAPA2 | c.5484C>G p.L1828= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as rs1432095746, COSV52491833; called by muse, mutect2
- SEC14L1 | c.243C>T p.V81= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as COSV101171260, COSV66722523; called by muse, mutect2, varscan2
- SEMA6A | c.2304G>C p.R768= | Silent (SNP) | VAF 28/116 reads (24%) | catalogued as COSV99146107; called by muse, mutect2, varscan2
- SLC46A2 | c.1254C>A p.T418= | Silent (SNP) | VAF 13/104 reads (13%) | catalogued as COSV100953547, COSV65290466; called by muse, mutect2, varscan2
- SLC4A3 | c.2475G>A p.E825= | Silent (SNP) | VAF 31/111 reads (28%) | catalogued as COSV56097077; called by muse, mutect2, varscan2
- SPTA1 | c.3711T>C p.D1237= | Silent (SNP) | VAF 24/103 reads (23%) | catalogued as rs373848368; called by muse, mutect2, varscan2
- STK33 | c.552G>C p.T184= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV100174669; called by muse, varscan2
- TACR2 | c.174C>A p.I58= | Silent (SNP) | VAF 18/35 reads (51%) | catalogued as COSV100964837, COSV64822438; called by muse, mutect2, varscan2
- TMEM81 | c.327C>T p.I109= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV99197054; called by muse, mutect2, varscan2
- TRBC2 | c.141G>A p.V47= | Silent (SNP) | VAF 12/59 reads (20%) | called by muse, mutect2, varscan2
- MACROD2 | c.418+165049G>T | Intron (SNP) | VAF 3/22 reads (14%) | called by muse, mutect2
- PRR12 | chr19:49595115 G>A | 5'Flank (SNP) | VAF 4/14 reads (29%) | catalogued as COSV99882620; called by muse, mutect2, varscan2
